Surgical pathology report (de-identified scan), TCGA case TCGA-38-4630, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4630-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

A: Lung, right upper lobe, lobectomy
- Adenocarcinoma, poorly differentiated, with focal papillary architecture, 4.5 cm diameter, morphologically similar to previous uterine papillary serous carcinoma, bronchial margin not involved, pleural margin focally involved (see light microscopy)

B: Lymph node, Station 7, biopsy
- No metastatic carcinoma identified (0/1)

C: Lymph node, R9, biopsy
- No metastatic carcinoma identified (0/4)

D: Lymph node, R10, biopsy
- No metastatic carcinoma identified (0/2)

Comment:
None

Intraoperative Consultation:
A frozen section is requested by Dr

FSA1: Right upper lobe, lobectomy, bronchial margin
- No in situ or invasive carcinoma identified

Clinical History:
The patient is with non-small cell lung carcinoma of the right upper lobe.

Gross Description:
Received are four appropriately containers.

Container A is additionally labeled "right upper lobe." Within is a plastic yellow biopsy cassette labeled FSA1. Also within is the lobectomy specimen.

Specimen fixation: formalin

Type of specimen/parts of lung received: right upper lobe partial lobectomy

Size of specimen: 13 x 12 x 4.5 cm

Weight of specimen: 220 grams

Other attached structures: none

Tumor size: 4.5 x 4.1 x 3.5 cm

Tumor description: ovoid, circumscribed, tan and solid with central softening

Relationship of tumor to bronchus: directly involving a medium sized bronchus

Distance of tumor to bronchial margin: 9 mm

Relationship/distance of tumor to pleura: the tumor grossly comes to within 1 mm of the visceral pleural surface but not directly involving it (the overlying pleura is pink/purple and smooth)

Distance of tumor to other surgical margins: a 9 cm linear stapled margin of resection runs parallel to the longitudinal axis of the ovoid tumor; the tumors closest approximation to this stapled margin is approximately 1 cm

Presence/absence of satellite tumor nodules: absent

Description of nontumorous lung: unremarkable pulmonary parenchyma

Block Summary:

A1,A2 - tumors relationship to bronchus
A3,A4 - tumors relationship to pleura
A5 - tumor
A6 - tumor at area of central softening
A7 - tumor/normal parenchymal interface
A8 - representative sections of normal parenchyma
A9 - en face section of previously inked hilum

Container B is additionally labeled "station 7." Within are two brown/black soft

[page 2 of 2]
tissue fragments measuring 1.1 x 0.5 x 0.4 cm in aggregate. ()

Container C is additionally labeled "R9." It holds a 1.5 x 0.6 x 0.5 cm tan/gray soft tissue specimen is bisected and entirely submitted in block C1.

Container D is additionally labeled "R10 lymph node." Within is a 0.9 x 0.5 x 0.4 cm tan/gray soft tissue specimen which is bisected and entirely submitted in block D1

Light Microscopy:

Light microscopic examination is performed by Dr.

The frozen section diagnosis is confirmed.

(Specimen A)

Tumor histologic type (WHO classification): adenocarcinoma, with focal papillary features

Tumor histologic grade (WHO classification): poorly differentiated

Tumor size (greatest dimension): 4.5 cm diameter

Histologic assessment of surgical margins: bronchial margin not involved

Pleural involvement: focally (+) (block A3)

In situ carcinoma: no definite in situ carcinoma identified

Invasion:

angiolymphatic - present (small vein)

perineural - not identified

Lymph nodes (by node group): no metastatic carcinoma identified (0/7 total)

Source: NCI Genomic Data Commons file ed12276a-56f2-4f4c-ae9f-27b452faca2b (TCGA-38-4630.63D133EB-0AA7-4C76-BF48-B9206DF8975F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).